Somatic mutation profile of tumor specimen TCGA-WB-A820-01A (aliquot TCGA-WB-A820-01A-11D-A35I-08) from TCGA case TCGA-WB-A820, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 40.9 years (14,949 days).
Specimen TCGA-WB-A820-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6c998be-a2cd-44d3-9e39-e5061a7439a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A820-10A (Blood Derived Normal), aliquot TCGA-WB-A820-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88f59235-70a7-49ed-9702-6782a9216835

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPP9 | c.344C>T p.T115M (on ENST00000598800; = p.T144M on NM_139159.5) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs994294799, COSV53594978; called by muse, mutect2, varscan2
- MUC16 | c.26902C>T p.P8968S | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as rs558927351, COSV67500593; called by muse, mutect2
- PVALB | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs748683112, COSV99342815; called by muse, mutect2, varscan2
- ATRX | c.3904dup p.R1302Kfs*7 | Frame Shift Ins (INS) | VAF 26/46 reads (57%) | called by mutect2, varscan2
- ELOA | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- H1-0 | c.340A>G p.I114V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN14 | c.3414C>G p.I1138M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SHPRH | c.2383C>A p.L795I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- SLC12A4 | c.1501T>A p.W501R | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- MAN1B1 | c.1482C>A p.V494= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- NFIC | c.432G>A p.E144= | Silent (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- QPCT | c.606G>A p.E202= | Silent (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- THSD7B | c.4038C>T p.V1346= (on ENST00000272643; = p.V1344= on NM_001316349.2) | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs761653221; called by muse, mutect2, varscan2
